Somatic mutation profile of tumor specimen MMRF_1029_1_BM_CD138pos (aliquot MMRF_1029_1_BM_CD138pos_T2_KAS5U_L02446) from MMRF case MMRF_1029, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 46.7 years (17,048 days).
Specimen MMRF_1029_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5d0541fb-e495-481d-a240-f361fdeeacf0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1029_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1029_1_PB_Whole_C3_KAS5U_L02456; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4e1ead87-e23d-493c-a304-35861fd83469

The open-access MAF lists 98 somatic variants for this specimen: 46 protein-altering or splice-affecting, 11 silent, 41 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, 3'UTR 21, Intron 12, Silent 11, 5'Flank 3, Frame Shift Del 2, RNA 2, Nonsense Mutation 2, 5'UTR 2, 3'Flank 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1A | c.3274G>A p.A1092T | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as rs371820430; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNOT1 | c.4493A>C p.D1498A | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV55321904; called by muse, mutect2, varscan2
- CYLC2 | c.657A>C p.K219N | Missense Mutation (SNP) | VAF 47/87 reads (54%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.845); catalogued as COSV66336356, COSV66339242; called by muse, mutect2, varscan2
- IGKV1-5 | c.150T>G p.S50R | Missense Mutation (SNP) | VAF 26/27 reads (96%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs754010051; called by muse, varscan2
- IGKV1-5 | c.149G>T p.S50I | Missense Mutation (SNP) | VAF 26/26 reads (100%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as rs11546104; called by muse, varscan2
- IGKV1-5 | c.97C>G p.L33V | Missense Mutation (SNP) | VAF 32/32 reads (100%) | SIFT tolerated (0.09); PolyPhen benign (0.165); catalogued as rs550955924; called by muse, varscan2
- IGSF9B | c.3506G>A p.R1169Q | Missense Mutation (SNP) | VAF 52/74 reads (70%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs772351117; called by muse, mutect2, varscan2
- KRTAP21-3 | c.169T>C p.C57R | Missense Mutation (SNP) | VAF 124/327 reads (38%) | PolyPhen benign (0); catalogued as rs775627170, COSV71480740; called by muse, mutect2, varscan2
- LAMA3 | c.8939C>G p.T2980S (on ENST00000313654 / NM_198129.4; = p.T1371S on NM_000227.6) | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as COSV52544430; called by muse, mutect2, varscan2
- LRFN2 | c.538C>A p.L180M | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV100599553; called by muse, mutect2, varscan2
- LRRC74B | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs1431462833; called by muse, mutect2, varscan2
- MUC16 | c.34148C>T p.P11383L | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.069); catalogued as COSV67490765; called by muse, mutect2
- MYH1 | c.4286T>G p.V1429G | Missense Mutation (SNP) | VAF 57/138 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV56847433; called by muse, mutect2, varscan2
- NDST4 | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as rs767236676, COSV52123386; called by muse, mutect2, varscan2
- PCSK5 | c.5308C>T p.R1770* | Nonsense Mutation (SNP) | VAF 25/134 reads (19%) | catalogued as rs775532268; called by muse, mutect2, varscan2
- TRAJ49 | c.49G>A p.V17I | Missense Mutation (SNP) | VAF 34/179 reads (19%) | PolyPhen probably damaging (0.994); catalogued as rs1372764377; called by muse, mutect2, varscan2
- VEGFC | c.931G>A p.D311N | Missense Mutation (SNP) | VAF 45/100 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV54595012; called by muse, mutect2, varscan2
- ZNF778 | c.2086A>G p.T696A | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.374); catalogued as rs936476113; called by muse, mutect2, varscan2
- ADAMTS8 | c.2081G>T p.G694V | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- AGO2 | c.2271+5G>A | Splice Region (SNP) | VAF 13/86 reads (15%) | called by muse, mutect2, varscan2
- ASCC3 | c.2652C>A p.N884K | Missense Mutation (SNP) | VAF 15/161 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.017); called by muse, mutect2
- BAIAP2 | c.1519G>A p.A507T | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC62 | c.413T>C p.L138P | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2
- CD274 | c.611_614del p.N204Rfs*10 | Frame Shift Del (DEL) | VAF 65/149 reads (44%) | called by mutect2, pindel, varscan2
- DNAH1 | c.689C>T p.T230I | Missense Mutation (SNP) | VAF 102/318 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- DUSP8 | c.442A>C p.S148R | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.726); called by mutect2, varscan2
- F13A1 | c.1561A>T p.M521L | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- F2R | c.654G>C p.R218S | Missense Mutation (SNP) | VAF 44/77 reads (57%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITGB2 | c.579C>G p.N193K | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2
- MTMR2 | c.641A>T p.E214V | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYH2 | c.2645A>T p.K882M | Missense Mutation (SNP) | VAF 16/294 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- PABPN1 | c.466+2T>C p.X156_splice | Splice Site (SNP) | VAF 26/139 reads (19%) | called by muse, mutect2, varscan2
- PDS5A | c.1346A>G p.K449R | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PLCB3 | c.2410A>G p.K804E | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); called by muse, mutect2
- PPP1R21 | c.1320T>G p.D440E | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- PPP1R21 | c.1433A>G p.N478S | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.87); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- SIGLEC8 | c.1414G>T p.E472* | Nonsense Mutation (SNP) | VAF 37/112 reads (33%) | called by muse, mutect2, varscan2
- SP3 | c.1841del p.N614Ifs*25 | Frame Shift Del (DEL) | VAF 12/38 reads (32%) | called by mutect2, pindel
- TMC1 | c.548C>T p.S183F | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- TNFRSF10D | c.698G>C p.R233P | Missense Mutation (SNP) | VAF 60/116 reads (52%) | SIFT tolerated (0.32); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- UHMK1 | c.757A>G p.N253D | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- WDR3 | c.220T>G p.S74A | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- WHRN | c.463A>C p.S155R | Missense Mutation (SNP) | VAF 46/154 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF136 | c.633T>G p.F211L | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF557 | c.690A>C p.E230D (on ENST00000414706 / NM_001044388.2; = p.E237D on NM_024341.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 98/137 reads (72%) | SIFT deleterious (0.03); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- ZSCAN5C | c.852C>A p.H284Q | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- ASB10 | c.1368C>T p.R456= (on ENST00000420175 / NM_001142459.2; = p.R441= on NM_080871.4) | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs1402470622; called by muse, mutect2
- B4GALNT4 | c.2343G>T p.L781= | Silent (SNP) | VAF 19/59 reads (32%) | called by muse, mutect2, varscan2
- FMN2 | c.2424A>T p.S808= | Silent (SNP) | VAF 103/207 reads (50%) | called by muse, mutect2, varscan2
- GLI2 | c.3957C>G p.G1319= (on ENST00000361492 / NM_001374353.1; = p.G1336= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/67 reads (10%) | called by muse, mutect2, varscan2
- IGKV1-5 | c.336G>A p.Q112= | Silent (SNP) | VAF 15/15 reads (100%) | catalogued as rs111612902; called by muse, varscan2
- MYH15 | c.5028C>T p.N1676= | Silent (SNP) | VAF 12/38 reads (32%) | called by muse, mutect2, varscan2
- OR2T27 | c.48T>A p.G16= | Silent (SNP) | VAF 8/162 reads (5%) | called by muse, mutect2
- OR2T4 | c.750T>C p.Y250= | Silent (SNP) | VAF 81/190 reads (43%) | called by muse, mutect2
- PDIA5 | c.1269C>T p.A423= | Silent (SNP) | VAF 15/103 reads (15%) | called by muse, mutect2, varscan2
- SDK1 | c.2112C>T p.I704= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as rs762707264; called by muse, mutect2
- SLC24A2 | c.1977C>T p.V659= | Silent (SNP) | VAF 14/73 reads (19%) | called by muse, mutect2, varscan2
- AAK1 | c.*10247C>T | 3'UTR (SNP) | VAF 25/54 reads (46%) | catalogued as rs531021526; called by muse, mutect2, varscan2
- AC008060.1 | n.630A>T | RNA (SNP) | VAF 21/117 reads (18%) | called by muse, mutect2, varscan2
- ADAM7 | c.634-458C>T | Intron (SNP) | VAF 7/50 reads (14%) | called by muse, mutect2, varscan2
- AFAP1L1 | c.*1106G>C | 3'UTR (SNP) | VAF 7/59 reads (12%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65499296 C>T | 5'Flank (SNP) | VAF 14/59 reads (24%) | catalogued as rs1565674529; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65499386 T>G | 5'Flank (SNP) | VAF 12/55 reads (22%) | called by muse, mutect2, varscan2
- ARG1 | c.*226T>C | 3'UTR (SNP) | VAF 48/90 reads (53%) | called by muse, mutect2, varscan2
- C11orf87 | c.*3508A>G | 3'UTR (SNP) | VAF 14/202 reads (7%) | called by muse, mutect2
- C16orf97 | n.124C>T | RNA (SNP) | VAF 3/26 reads (12%) | called by muse, mutect2
- CD46 | c.*1234T>C | 3'UTR (SNP) | VAF 10/37 reads (27%) | catalogued as rs923354967; called by muse, mutect2, varscan2
- CEP85L | c.*366G>A | 3'UTR (SNP) | VAF 6/54 reads (11%) | called by muse, mutect2, varscan2
- DCAF12 | c.862-45A>G | Intron (SNP) | VAF 23/51 reads (45%) | called by muse, mutect2, varscan2
- DCC | c.*4440T>A | 3'UTR (SNP) | VAF 6/13 reads (46%) | called by muse, mutect2, varscan2
- DTX1 | c.-418G>A | 5'UTR (SNP) | VAF 12/21 reads (57%) | catalogued as rs1329505510; called by muse, varscan2
- DTX1 | c.-373A>G | 5'UTR (SNP) | VAF 17/35 reads (49%) | called by muse, varscan2
- ENTPD2 | c.*375T>C | 3'UTR (SNP) | VAF 21/60 reads (35%) | called by muse, mutect2, varscan2
- FABP1 | c.333+82C>T | Intron (SNP) | VAF 5/36 reads (14%) | called by muse, mutect2, varscan2
- FAM241B | c.-104+235G>C | Intron (SNP) | VAF 6/44 reads (14%) | called by muse, mutect2
- GAREM1 | c.*2458G>A | 3'UTR (SNP) | VAF 12/44 reads (27%) | called by muse, mutect2, varscan2
- GNB4 | c.*505C>G | 3'UTR (SNP) | VAF 11/102 reads (11%) | called by muse, mutect2, varscan2
- IGSF10 | c.*1097del | 3'UTR (DEL) | VAF 86/138 reads (62%) | called by mutect2, varscan2
- KANSL3 | c.*579A>T | 3'UTR (SNP) | VAF 10/116 reads (9%) | called by muse, mutect2
- LRRC28 | c.*4413A>G | 3'UTR (SNP) | VAF 21/68 reads (31%) | called by muse, mutect2, varscan2
- LTB | c.163-40C>G | Intron (SNP) | VAF 148/266 reads (56%) | catalogued as rs115773593; called by muse, mutect2, varscan2
- MIR5195 | chr14:106851266 C>T | 5'Flank (SNP) | VAF 49/116 reads (42%) | catalogued as rs545752688; called by muse, mutect2, varscan2
- PCSK5 | c.2626+4380G>A | Intron (SNP) | VAF 45/114 reads (39%) | called by muse, mutect2, varscan2
- PMEPA1 | c.109+9441G>T | Intron (SNP) | VAF 16/85 reads (19%) | called by muse, mutect2, varscan2
- POLR3H | c.111+43G>C | Intron (SNP) | VAF 10/106 reads (9%) | called by muse, mutect2
- RYR2 | c.*195T>G | 3'UTR (SNP) | VAF 62/130 reads (48%) | called by muse, mutect2, varscan2
- SLC16A11 | c.275-67A>G | Intron (SNP) | VAF 5/19 reads (26%) | called by muse, mutect2, varscan2
- SLC6A19 | c.*1729C>T | 3'UTR (SNP) | VAF 30/123 reads (24%) | catalogued as rs565526025; called by muse, mutect2, varscan2
- SRGAP1 | c.1814-18G>A | Intron (SNP) | VAF 25/60 reads (42%) | called by muse, mutect2, varscan2
- SYBU | c.*180T>A | 3'UTR (SNP) | VAF 47/93 reads (51%) | called by muse, varscan2
- SYBU | c.*115T>C | 3'UTR (SNP) | VAF 66/128 reads (52%) | catalogued as rs184534050, COSV99406373; called by muse, varscan2
- TF | c.1688-668G>T | Intron (SNP) | VAF 11/32 reads (34%) | called by muse, mutect2
- TIAM2 | chr6:155257616 G>A | 3'Flank (SNP) | VAF 28/42 reads (67%) | called by muse, mutect2, varscan2
- TMTC4 | c.*334G>A | 3'UTR (SNP) | VAF 6/10 reads (60%) | catalogued as rs963508075; called by muse, mutect2, varscan2
- TMX4 | c.*3631A>G | 3'UTR (SNP) | VAF 19/35 reads (54%) | called by muse, mutect2, varscan2
- TNFRSF11A | c.*521C>A | 3'UTR (SNP) | VAF 29/53 reads (55%) | called by muse, mutect2, varscan2
- TNFRSF9 | c.*499A>G | 3'UTR (SNP) | VAF 31/60 reads (52%) | called by muse, mutect2, varscan2
- ZNF711 | c.917-946T>C | Intron (SNP) | VAF 64/67 reads (96%) | called by muse, mutect2, varscan2
